Somatic mutation profile of tumor specimen MMRF_1978_1_BM_CD138pos (aliquot MMRF_1978_1_BM_CD138pos_T1_KHS5U_L08116) from MMRF case MMRF_1978, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.1 years (26,709 days).
Specimen MMRF_1978_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6993e041-55bb-4a7c-83b2-7271df2c5995.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1978_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1978_1_PB_WBC_C2_KHS5U_L08117; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dd7fbda-3a7b-4f04-ad1e-89b58dd26f14

The open-access MAF lists 95 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 30, Silent 12, Intron 9, 5'Flank 4, 5'UTR 3, Splice Site 1, Frame Shift Del 1, 3'Flank 1, Splice Region 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNB1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039396, COSV65570538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC093246.1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs984975545, COSV51125252; called by muse, varscan2
- ACRV1 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs183418543, COSV59755557; called by muse, mutect2, varscan2
- ATP2B3 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs201753621, COSV54851969; called by muse, mutect2, varscan2
- IGKV1-5 | c.157A>T p.S53C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs374936658; called by muse, varscan2
- IGKV1-5 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565389732; called by muse, varscan2
- IGKV1-8 | c.243G>C p.R81S | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs548841496; called by muse, mutect2, varscan2
- ISM1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs377416231; called by muse, mutect2
- JADE1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1176782190; called by muse, mutect2
- KCNJ4 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs753595753, COSV57856295; called by muse, mutect2, varscan2
- KIF9 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1424782662; called by muse, mutect2, varscan2
- LGMN | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs1488328832, COSV58403475; called by muse, mutect2, varscan2
- N4BP3 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs535658994; called by muse, mutect2, varscan2
- NXF1 | c.801A>G p.L267= | Splice Region (SNP) | VAF 35/96 reads (36%) | catalogued as rs146549860; called by muse, mutect2, varscan2
- PCDHA12 | c.2185G>A p.V729M | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV56549136; called by muse, mutect2, varscan2
- PKNOX2 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 18/258 reads (7%) | catalogued as rs778476842; called by muse, mutect2
- TBC1D12 | c.1462A>G p.S488G | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1237704207; called by muse, mutect2, varscan2
- UBA3 | c.428+1G>A p.X143_splice | Splice Site (SNP) | VAF 34/103 reads (33%) | catalogued as rs1041085271, COSV100734746; called by muse, mutect2, varscan2
- UBXN1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1471191573, COSV53657439; called by muse, mutect2, varscan2
- ZDHHC14 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as rs1226545584; called by muse, mutect2, varscan2
- ABI3BP | c.1390A>G p.K464E | Missense Mutation (SNP) | VAF 103/184 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ADGRB3 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ATP11A | c.2786T>C p.I929T | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CDX4 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DAOA | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ESYT2 | c.2536A>C p.K846Q (on ENST00000613624; = p.K770Q on NM_020728.3) | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- KCNA5 | c.1232T>G p.F411C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KISS1 | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- MADD | c.1978C>G p.L660V | Missense Mutation (SNP) | VAF 5/121 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.335); called by muse, mutect2
- REV3L | c.5475del p.D1826Mfs*5 | Frame Shift Del (DEL) | VAF 71/224 reads (32%) | called by mutect2, pindel, varscan2
- SLC4A7 | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- TRIO | c.5248G>T p.V1750L | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.049); called by muse, mutect2
- USH2A | c.2932G>C p.A978P | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ZNF572 | c.964C>A p.H322N | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC004922.1 | c.831C>T p.R277= | Silent (SNP) | VAF 48/77 reads (62%) | catalogued as rs143044515; called by muse, mutect2, varscan2
- ASIC1 | c.1554G>A p.P518= | Silent (SNP) | VAF 79/225 reads (35%) | catalogued as rs1438234453; called by muse, mutect2, varscan2
- EPHA6 | c.2406G>T p.G802= (on ENST00000389672 / NM_001080448.3; = p.G194= on NM_173655.4) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs781018815; called by muse, mutect2, varscan2
- GPSM1 | c.1767C>T p.H589= | Silent (SNP) | VAF 49/200 reads (25%) | catalogued as rs782156042, COSV52517878; called by muse, mutect2, varscan2
- IGHD6-13 | c.3G>A p.G1= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs782246656; called by muse, mutect2, varscan2
- MYO19 | c.2244T>C p.S748= (on ENST00000614623 / NM_001163735.1; = p.S548= on NM_025109.5) | Silent (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- PLXNB1 | c.2550C>T p.P850= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs774347842; called by muse, mutect2, varscan2
- RTL1 | c.1353C>T p.Y451= | Silent (SNP) | VAF 59/171 reads (35%) | catalogued as rs539590557; called by muse, mutect2, varscan2
- TP73 | c.693C>T p.T231= | Silent (SNP) | VAF 48/143 reads (34%) | catalogued as rs772632573; called by muse, mutect2, varscan2
- WDR81 | c.5754C>T p.S1918= (on ENST00000409644 / NM_001163809.2; = p.S867= on NM_152348.4) | Silent (SNP) | VAF 60/165 reads (36%) | catalogued as COSV100488642; called by muse, mutect2, varscan2
- XDH | c.1551C>T p.F517= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- ZNF26 | c.48C>T p.F16= | Silent (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- ABCA8 | c.797+162G>A | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as rs541422233; called by muse, varscan2
- ACTR8 | c.*54G>A | 3'UTR (SNP) | VAF 70/394 reads (18%) | called by muse, mutect2, varscan2
- ANKRD42 | chr11:83193582 T>G | 5'Flank (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2
- CBFA2T2 | c.*1183C>T | 3'UTR (SNP) | VAF 56/108 reads (52%) | catalogued as rs575864344; called by muse, mutect2, varscan2
- CC2D1B | c.*298G>A | 3'UTR (SNP) | VAF 18/242 reads (7%) | catalogued as rs760482574; called by muse, mutect2
- CD79B | c.*292G>A | 3'UTR (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- CNKSR2 | c.*870T>C | 3'UTR (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
- CRISPLD1 | c.*503del | 3'UTR (DEL) | VAF 31/89 reads (35%) | catalogued as rs1306035305; called by mutect2, pindel, varscan2
- CSRNP2 | c.*1795G>A | 3'UTR (SNP) | VAF 8/74 reads (11%) | catalogued as rs1006635622; called by muse, mutect2, varscan2
- CXXC4 | c.*2073T>G | 3'UTR (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- DLL4 | c.394+59A>T | Intron (SNP) | VAF 14/92 reads (15%) | catalogued as rs758333373; called by muse, mutect2, varscan2
- DPYSL5 | c.*1970G>T | 3'UTR (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- EQTN | c.-39G>C | 5'UTR (SNP) | VAF 20/438 reads (5%) | called by muse, mutect2
- FAT4 | c.*212T>G | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- FERMT2 | c.*4G>A | 3'UTR (SNP) | VAF 29/106 reads (27%) | catalogued as COSV100448597; called by muse, mutect2, varscan2
- FSCB | c.*190C>T | 3'UTR (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- GYS2 | c.*368C>T | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- H6PD | c.*5904G>C | 3'UTR (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- HEBP2 | chr6:138403599 G>C | 5'Flank (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- HHIPL1 | c.*2186C>T | 3'UTR (SNP) | VAF 27/68 reads (40%) | catalogued as rs777755543; called by muse, mutect2, varscan2
- HLX | c.-384A>G | 5'UTR (SNP) | VAF 71/169 reads (42%) | called by muse, mutect2, varscan2
- HTRA1 | c.*319T>G | 3'UTR (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- ICAM3 | c.1442-23G>A | Intron (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- KIAA1958 | c.1172-27345C>T | Intron (SNP) | VAF 9/194 reads (5%) | catalogued as rs1469345287; called by muse, mutect2
- KIF3B | c.*415A>G | 3'UTR (SNP) | VAF 74/175 reads (42%) | called by muse, mutect2, varscan2
- LANCL2 | c.*741A>G | 3'UTR (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851258 C>T | 5'Flank (SNP) | VAF 62/175 reads (35%) | catalogued as rs147455610; called by muse, mutect2, varscan2
- NCL | c.*838G>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | catalogued as rs1471870278; called by muse, mutect2
- NEUROD1 | c.*26G>A | 3'UTR (SNP) | VAF 22/57 reads (39%) | catalogued as COSV54548040; called by muse, mutect2, varscan2
- NLGN3 | c.*996A>T | 3'UTR (SNP) | VAF 15/58 reads (26%) | catalogued as rs1459651475; called by mutect2, varscan2
- PDXK | c.*3119C>G | 3'UTR (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- PRDM2 | c.5036+5118G>A | Intron (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- PTAR1 | c.*1675_*1682del | 3'UTR (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- RELCH | c.*265T>A | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- RPRD2 | c.436+317T>A | Intron (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- SAR1B | c.*2910T>C | 3'UTR (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- SEPHS2 | c.*447T>G | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- SETD6 | chr16:58515507 G>A | 5'Flank (SNP) | VAF 17/32 reads (53%) | catalogued as COSV50753669; called by muse, mutect2, varscan2
- SRI | chr7:88202605 A>C | 3'Flank (SNP) | VAF 70/159 reads (44%) | called by muse, mutect2, varscan2
- TBL2 | c.598+58A>G | Intron (SNP) | VAF 8/60 reads (13%) | catalogued as rs1398532959; called by muse, mutect2
- TFAP2E | c.562+2462G>A | Intron (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.439-22G>A | Intron (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- TMEM260 | c.*1858C>G | 3'UTR (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- TNFRSF10D | c.-58C>G | 5'UTR (SNP) | VAF 35/468 reads (7%) | called by muse, mutect2
- TNS3 | c.*1980T>G | 3'UTR (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- TPMT | c.*2085G>A | 3'UTR (SNP) | VAF 76/159 reads (48%) | called by muse, mutect2, varscan2
- TTC3P1 | n.4788A>G | RNA (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2
- UNC5C | c.*1381G>A | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
